Somatic mutation profile of tumor specimen ALCH-B1U8-TTP1-A (aliquot ALCH-B1U8-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1U8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 76.7 years (28,014 days).
Specimen ALCH-B1U8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc96e095-6305-4600-b828-6c9994e0b3a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1U8-NB1-A (Blood Derived Normal), aliquot ALCH-B1U8-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7f754d3-9149-4041-ad4e-42c22f163857

The open-access MAF lists 352 somatic variants for this specimen: 252 protein-altering or splice-affecting, 66 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 220, Silent 66, Nonsense Mutation 16, Intron 15, RNA 8, Splice Site 6, Frame Shift Del 5, Frame Shift Ins 4, 3'Flank 3, 3'UTR 3, 5'Flank 3, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.1700G>T p.R567M | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61255222; called by muse, mutect2, varscan2
- ADAMTS16 | c.1942C>A p.R648S | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57001543; called by muse, mutect2, varscan2
- ADAMTS16 | c.1943G>T p.R648L | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375485579; called by muse, mutect2, varscan2
- ANKRD36 | c.3157A>G p.R1053G | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.824); catalogued as rs1213362288, COSV70741313; called by muse, varscan2
- ARID1A | c.6670G>T p.E2224* | Nonsense Mutation (SNP) | VAF 22/66 reads (33%) | catalogued as COSV100250527; called by muse, mutect2, varscan2
- BDKRB1 | c.926C>A p.P309Q | Missense Mutation (SNP) | VAF 80/467 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53706682; called by muse, mutect2, varscan2
- CCN3 | c.967A>T p.K323* | Nonsense Mutation (SNP) | VAF 51/241 reads (21%) | catalogued as COSV52383032; called by muse, mutect2, varscan2
- CD300C | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 67/275 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV99043777; called by muse, mutect2, varscan2
- CDH12 | c.646G>C p.G216R | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1561244779, COSV66393074; called by muse, mutect2, varscan2
- CLCN7 | c.2323C>T p.R775C | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs144511808; called by muse, mutect2, varscan2
- CLHC1 | c.888C>G p.H296Q | Missense Mutation (SNP) | VAF 223/296 reads (75%) | SIFT tolerated (0.26); PolyPhen benign (0.113); catalogued as rs978093185; called by muse, mutect2, varscan2
- COX6B1 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 79/329 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.393); catalogued as rs111638609; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPED1 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 71/232 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.167); catalogued as COSV60015377; called by muse, mutect2, varscan2
- CROT | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58973444; called by muse, mutect2, varscan2
- CSPP1 | c.1252G>T p.D418Y (on ENST00000676605; = p.D377Y on NM_024790.6) | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1362751399; called by muse, mutect2, varscan2
- CYLC1 | c.353C>A p.S118Y | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.054); catalogued as rs769298767, COSV61414922; called by muse, mutect2, varscan2
- DDX21 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 42/222 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as rs1212918050, COSV62555043; called by muse, mutect2, varscan2
- DISP3 | c.2282G>T p.R761L | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV53832263; called by muse, mutect2, varscan2
- DMBT1 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 69/651 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369499397; called by muse, mutect2, varscan2
- DNAH5 | c.3140G>T p.G1047V | Missense Mutation (SNP) | VAF 59/530 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs766536260, COSV54242079, COSV54252241; called by muse, mutect2, varscan2
- DNAJC16 | c.1867A>T p.M623L | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as rs759059472; called by muse, mutect2, varscan2
- DPP10 | c.230A>G p.K77R | Missense Mutation (SNP) | VAF 81/322 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs773562921, COSV59666066; called by muse, mutect2, varscan2
- EDNRB | c.1226G>T p.R409L (on ENST00000377211 / NM_001201397.1; = p.R319L on NM_000115.5) | Missense Mutation (SNP) | VAF 102/313 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs759543922, CM073024, COSV57523127; called by muse, mutect2, varscan2
- ENPP1 | c.1987A>G p.R663G | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs776683717; called by muse, mutect2, varscan2
- EVX1 | c.590G>T p.R197L | Missense Mutation (SNP) | VAF 164/443 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761052705, COSV56085406; called by muse, mutect2, varscan2
- FBN3 | c.268T>C p.C90R | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1284086083; called by muse, mutect2, varscan2
- FBXO28 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.986); catalogued as COSV64801267; called by muse, mutect2, varscan2
- GPX6 | c.529C>A p.H177N | Missense Mutation (SNP) | VAF 95/416 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs745601317; called by muse, mutect2, varscan2
- GRAMD1A | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.029); catalogued as rs754745864; called by muse, mutect2, varscan2
- GRID1 | c.1648G>T p.E550* | Nonsense Mutation (SNP) | VAF 59/355 reads (17%) | catalogued as COSV60037899; called by muse, mutect2, varscan2
- HHAT | c.1127G>A p.S376N | Missense Mutation (SNP) | VAF 167/283 reads (59%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as COSV54812478; called by muse, mutect2, varscan2
- IGSF10 | c.92G>C p.R31P | Missense Mutation (SNP) | VAF 50/361 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs374510873, COSV99193968; called by muse, mutect2, varscan2
- JAKMIP2 | c.1373C>A p.P458Q | Missense Mutation (SNP) | VAF 152/318 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99508963; called by muse, mutect2, varscan2
- JHY | c.2327A>C p.H776P | Missense Mutation (SNP) | VAF 143/217 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99074651; called by muse, mutect2, varscan2
- KIF20A | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 69/323 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs781714038; called by muse, mutect2, varscan2
- KLHL30 | c.1103C>A p.T368N | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1036994770; called by muse, mutect2, varscan2
- KLHL4 | c.1915T>A p.C639S | Missense Mutation (SNP) | VAF 62/86 reads (72%) | SIFT tolerated (0.14); PolyPhen benign (0.34); catalogued as rs1220209531; called by muse, mutect2, varscan2
- LIFR | c.1079C>G p.A360G | Missense Mutation (SNP) | VAF 68/431 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54690950; called by muse, mutect2, varscan2
- LRP1B | c.13139G>T p.C4380F | Missense Mutation (SNP) | VAF 122/409 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67256863; called by muse, mutect2, varscan2
- LRP1B | c.11850G>C p.R3950S | Missense Mutation (SNP) | VAF 104/220 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV67200432; called by muse, mutect2, varscan2
- LRRC30 | c.836C>A p.P279H | Missense Mutation (SNP) | VAF 71/133 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67301773; called by muse, mutect2, varscan2
- LRRC59 | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 29/181 reads (16%) | catalogued as rs1163141995; called by muse, mutect2, varscan2
- LRTM1 | c.883G>T p.V295L | Missense Mutation (SNP) | VAF 90/430 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs1047682431; called by muse, mutect2, varscan2
- LURAP1 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs200435573; called by muse, mutect2, varscan2
- MAGI2 | c.2269C>T p.Q757* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as rs747282945, COSV62646014, COSV62656132; called by muse, mutect2, varscan2
- MEGF10 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 110/191 reads (58%) | SIFT tolerated (0.7); PolyPhen benign (0.095); catalogued as rs201393832; called by muse, mutect2, varscan2
- METTL8 | c.664C>G p.P222A | Missense Mutation (SNP) | VAF 97/310 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64552498; called by muse, mutect2, varscan2
- MKI67 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 92/200 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as COSV64073245; called by muse, mutect2, varscan2
- MRC2 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 42/65 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs749243892, COSV57642873; called by muse, mutect2, varscan2
- NDUFA12 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 64/423 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.117); catalogued as rs371084211; called by muse, mutect2, varscan2
- NDUFA9 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 400/566 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as rs778957183, COSV56928863, COSV56930784; called by muse, mutect2, varscan2
- NELL1 | c.657G>C p.Q219H | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs957460898, COSV54257251, COSV54279275; called by muse, mutect2, varscan2
- NEMP1 | c.655G>A p.V219I (on ENST00000300128 / NM_001130963.2; = p.V146I on NM_015257.3) | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs763305232, COSV55661751; called by muse, mutect2, varscan2
- NLRP5 | c.3283G>T p.V1095F | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.195); catalogued as COSV66766486; called by muse, mutect2, varscan2
- NPHS1 | c.2468C>A p.A823E | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.113); catalogued as COSV62288508; called by muse, mutect2, varscan2
- OBSCN | c.7394C>T p.S2465L | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.701); catalogued as COSV99472280; called by muse, varscan2
- PCDHB4 | c.1581G>T p.E527D | Missense Mutation (SNP) | VAF 71/346 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.246); catalogued as rs782479296, COSV52023574; called by muse, mutect2, varscan2
- PKHD1L1 | c.4568G>C p.G1523A | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV65750332; called by muse, varscan2
- PLEKHG6 | c.689C>T p.T230I | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs895481409, COSV99164850; called by muse, mutect2
- POLR3GL | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 32/254 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs782368633; called by muse, mutect2, varscan2
- POTEE | c.294G>T p.M98I | Missense Mutation (SNP) | VAF 57/247 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1206857910; called by muse, mutect2, varscan2
- POTEF | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 44/531 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV62544059; called by muse, mutect2
- POTEF | c.294G>T p.M98I | Missense Mutation (SNP) | VAF 45/538 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs750446868; called by muse, mutect2
- PTGER2 | c.600C>A p.Y200* | Nonsense Mutation (SNP) | VAF 65/236 reads (28%) | catalogued as COSV99817781; called by muse, mutect2, varscan2
- RYR1 | c.7229C>A p.P2410Q | Missense Mutation (SNP) | VAF 216/388 reads (56%) | SIFT tolerated (0.47); PolyPhen benign (0.024); catalogued as COSV100616972; called by muse, mutect2, varscan2
- RYR1 | c.11120G>T p.R3707L | Missense Mutation (SNP) | VAF 286/476 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as rs193922838, CM064216, COSV62089595, COSV62100969; ClinVar: not provided; called by muse, varscan2
- RYR3 | c.13559A>G p.Y4520C (on ENST00000389232; = p.Y4521C on NM_001036.6) | Missense Mutation (SNP) | VAF 108/295 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1268292076, COSV66812303; called by muse, mutect2, varscan2
- SAGE1 | c.1922C>A p.P641H | Missense Mutation (SNP) | VAF 65/183 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100186511; called by muse, mutect2, varscan2
- SCN7A | c.4324G>A p.A1442T | Missense Mutation (SNP) | VAF 150/535 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1172227994, COSV101313309; called by muse, mutect2, varscan2
- SELP | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 178/337 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV55258201; called by muse, mutect2, varscan2
- SEMA3C | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54847611; called by muse, mutect2, varscan2
- SIX2 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV100284182, COSV57392528; called by muse, mutect2, varscan2
- SLC18B1 | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV99259357; called by muse, mutect2, varscan2
- SLC5A7 | c.1642C>T p.R548* | Nonsense Mutation (SNP) | VAF 31/280 reads (11%) | catalogued as rs199636877; called by muse, mutect2, varscan2
- SLITRK3 | c.682C>G p.Q228E | Missense Mutation (SNP) | VAF 37/362 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99579573; called by muse, mutect2, varscan2
- SPRR2A | c.110C>A p.P37Q | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.7); catalogued as COSV66991201; called by muse, mutect2, varscan2
- SPRR2A | c.109C>A p.P37T | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.26); catalogued as rs774885465; called by muse, mutect2, varscan2
- SPTA1 | c.3796G>T p.E1266* | Nonsense Mutation (SNP) | VAF 89/587 reads (15%) | catalogued as COSV100934139; called by muse, mutect2, varscan2
- STAB2 | c.4396G>A p.G1466R | Missense Mutation (SNP) | VAF 121/203 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs772354918, COSV66348545; called by muse, mutect2, varscan2
- SYT8 | c.1086G>A p.M362I | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs1554968943; called by muse, mutect2, varscan2
- SYTL2 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 56/327 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1007879048; called by muse, mutect2, varscan2
- TCF20 | c.2831A>G p.N944S | Missense Mutation (SNP) | VAF 63/231 reads (27%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); catalogued as COSV59496980; called by muse, mutect2, varscan2
- TMEM132E | c.2500G>A p.E834K (on ENST00000321639; = p.E924K on NM_001304438.2) | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs1233870562, COSV58694672; called by muse, mutect2, varscan2
- TMEM63A | c.378C>G p.D126E | Missense Mutation (SNP) | VAF 72/117 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV99067540; called by muse, mutect2, varscan2
- TRHR | c.168G>A p.M56I | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61237025; called by muse, mutect2, varscan2
- TTC13 | c.1716G>C p.W572C | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100793018; called by muse, mutect2, varscan2
- UBN1 | c.336+1G>C p.X112_splice | Splice Site (SNP) | VAF 43/368 reads (12%) | catalogued as COSV52166680, COSV52169805; called by muse, mutect2, varscan2
- USP45 | c.2324C>T p.A775V | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs375582786; called by muse, mutect2, varscan2
- VSIG10 | c.101G>C p.G34A | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63654668; called by muse, varscan2
- VWDE | c.2513G>A p.C838Y | Missense Mutation (SNP) | VAF 93/350 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1435371900, COSV51731553; called by muse, mutect2, varscan2
- WBP11 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 38/349 reads (11%) | SIFT tolerated, low confidence (0.58); PolyPhen possibly damaging (0.462); catalogued as rs535254129, COSV53762397, COSV53763601; called by muse, varscan2
- WWTR1 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 70/118 reads (59%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs763906518; called by muse, mutect2, varscan2
- ZNF18 | c.380G>T p.W127L | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV59552416; called by muse, mutect2
- ZNF441 | c.1777G>T p.G593W | Missense Mutation (SNP) | VAF 101/214 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1278429356; called by muse, mutect2, varscan2
- ZNF446 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.866); catalogued as rs759130926; called by muse, mutect2, varscan2
- ZNF525 | c.1247G>T p.C416F | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV62492112; called by muse, mutect2, varscan2
- ZNF559 | c.1610G>A p.C537Y | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.087); catalogued as rs760427628; called by muse, mutect2, varscan2
- ZRANB3 | c.1531T>C p.F511L | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs770854036; called by muse, mutect2, varscan2
- ABCC5 | c.2132C>A p.P711H | Missense Mutation (SNP) | VAF 106/1270 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANK1 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKEF1 | c.1982del p.G661Afs*7 | Frame Shift Del (DEL) | VAF 23/187 reads (12%) | called by mutect2, pindel, varscan2
- ARHGEF18 | c.158A>G p.Q53R | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF4 | c.135G>T p.E45D | Missense Mutation (SNP) | VAF 164/407 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGEF9 | c.219G>C p.E73D | Missense Mutation (SNP) | VAF 57/160 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASAH2 | c.669G>T p.M223I | Missense Mutation (SNP) | VAF 119/468 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATP10D | c.3435C>A p.Y1145* | Nonsense Mutation (SNP) | VAF 93/377 reads (25%) | called by muse, mutect2, varscan2
- ATXN7L1 | c.1459C>A p.R487S | Missense Mutation (SNP) | VAF 88/355 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- B4GALNT3 | c.911A>G p.H304R | Missense Mutation (SNP) | VAF 47/616 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2
- BAG6 | c.301G>T p.G101W | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- BAZ1B | c.3677G>T p.W1226L | Missense Mutation (SNP) | VAF 55/277 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BBS5 | c.89T>G p.L30R | Missense Mutation (SNP) | VAF 85/213 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- BCHE | c.682G>T p.G228* | Nonsense Mutation (SNP) | VAF 142/230 reads (62%) | called by muse, mutect2, varscan2
- BSN | c.2569del p.L857Wfs*111 | Frame Shift Del (DEL) | VAF 41/84 reads (49%) | called by mutect2, pindel, varscan2
- C10orf71 | c.4090G>C p.G1364R | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- C16orf87 | c.21G>T p.K7N | Missense Mutation (SNP) | VAF 65/121 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); called by muse, varscan2
- C2orf16 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 62/87 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CAMK2A | c.693+1G>A p.X231_splice | Splice Site (SNP) | VAF 22/38 reads (58%) | called by muse, mutect2, varscan2
- CCDC168 | c.10154T>C p.L3385S | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CCDC39 | c.1057A>G p.N353D | Missense Mutation (SNP) | VAF 120/163 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CCN3 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 72/330 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCSER2 | c.25A>C p.T9P | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, varscan2
- CDCA2 | c.1616G>T p.R539M | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CDH18 | c.112dup p.T38Nfs*5 | Frame Shift Ins (INS) | VAF 150/563 reads (27%) | called by mutect2, pindel, varscan2
- CHRNA2 | c.684del p.S228Rfs*109 | Frame Shift Del (DEL) | VAF 86/289 reads (30%) | called by mutect2, pindel, varscan2
- CIART | c.1112G>C p.R371T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); called by mutect2, varscan2
- CLEC4E | c.236G>T p.C79F | Missense Mutation (SNP) | VAF 83/126 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CROCC2 | c.2417C>A p.T806K | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CRY2 | c.1433A>G p.K478R | Missense Mutation (SNP) | VAF 167/345 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CSPG5 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- DENND2A | c.1890-1G>T p.X630_splice | Splice Site (SNP) | VAF 45/144 reads (31%) | called by muse, mutect2, varscan2
- DLG3 | c.1394A>T p.Y465F (on ENST00000374360 / NM_021120.4; = p.Y128F on NM_020730.3) | Missense Mutation (SNP) | VAF 16/450 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.216); called by muse, mutect2
- DNAH11 | c.8008G>C p.A2670P | Missense Mutation (SNP) | VAF 170/538 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DNM1L | c.808C>T p.Q270* | Nonsense Mutation (SNP) | VAF 37/418 reads (9%) | called by muse, mutect2
- DOCK9 | c.2914C>G p.Q972E (on ENST00000376460 / NM_001366676.2; = p.Q973E on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- DST | c.19378A>T p.I6460L (on ENST00000361203 / NM_001374722.1; = p.I4157L on NM_015548.5) | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DYNC1H1 | c.8182C>G p.L2728V | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EFNB3 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPHA6 | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.086); called by muse, mutect2
- ESF1 | c.1315G>T p.D439Y | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- FAM131C | c.435G>T p.E145D | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM13A | c.217+1G>A p.X73_splice | Splice Site (SNP) | VAF 49/103 reads (48%) | called by muse, mutect2, varscan2
- FAM214B | c.941G>T p.R314L | Missense Mutation (SNP) | VAF 88/185 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM227B | c.417A>T p.E139D | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FZD10 | c.869G>A p.C290Y | Missense Mutation (SNP) | VAF 58/112 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRG3 | c.308C>G p.T103R | Missense Mutation (SNP) | VAF 64/356 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- GALNT17 | c.1691del p.G564Afs*116 | Frame Shift Del (DEL) | VAF 88/488 reads (18%) | called by mutect2, pindel, varscan2
- GEMIN5 | c.2243C>T p.T748I | Missense Mutation (SNP) | VAF 169/339 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GPR101 | c.875G>T p.G292V | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRM1 | c.304G>C p.G102R | Missense Mutation (SNP) | VAF 68/279 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HACD4 | c.604A>T p.M202L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.006); called by muse, mutect2
- IFNA1 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 89/258 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- IGHV1-58 | c.52C>A p.H18N | Missense Mutation (SNP) | VAF 102/229 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- IGHV3-66 | c.90G>C p.L30F | Missense Mutation (SNP) | VAF 42/294 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- IGKV2D-29 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 53/256 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- IL17A | c.380C>A p.P127Q | Missense Mutation (SNP) | VAF 67/265 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IL17F | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 112/359 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INVS | c.691G>C p.D231H | Missense Mutation (SNP) | VAF 105/389 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IPO13 | c.885G>T p.Q295H | Missense Mutation (SNP) | VAF 61/235 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- IQSEC3 | c.543C>A p.S181R | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.316); called by muse, mutect2
- ITPRIP | c.218C>A p.A73E | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- KAT6A | c.1196C>A p.S399Y | Missense Mutation (SNP) | VAF 82/381 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- KHDRBS3 | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- KIF17 | c.581A>T p.K194M | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- KIF19 | c.942C>A p.N314K | Missense Mutation (SNP) | VAF 104/147 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- L3MBTL3 | c.641G>T p.R214L | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- LAMA3 | c.6526G>T p.A2176S (on ENST00000313654 / NM_198129.4; = p.A567S on NM_000227.6) | Missense Mutation (SNP) | VAF 67/477 reads (14%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- LRP5 | c.2818A>T p.N940Y | Missense Mutation (SNP) | VAF 205/286 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- LRRC14B | c.944C>G p.A315G | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LRRC7 | c.4174T>A p.W1392R (on ENST00000651989 / NM_001370785.2; = p.W1312R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- LURAP1 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAD2L1 | c.311T>C p.I104T | Missense Mutation (SNP) | VAF 83/146 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- MAP3K15 | c.639G>T p.W213C | Missense Mutation (SNP) | VAF 141/242 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- MAP3K7 | c.610A>G p.S204G | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- MARCHF11 | c.1079C>A p.T360N | Missense Mutation (SNP) | VAF 135/692 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- MMS22L | c.1828A>T p.K610* | Nonsense Mutation (SNP) | VAF 43/198 reads (22%) | called by muse, mutect2, varscan2
- MUC16 | c.1743G>C p.W581C | Missense Mutation (SNP) | VAF 147/289 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- MYCT1 | c.419C>A p.A140D | Missense Mutation (SNP) | VAF 87/190 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MYO1C | c.433G>T p.G145C (on ENST00000648651 / NM_001080779.2; = p.G110C on NM_033375.5) | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NANOS1 | c.698A>G p.K233R | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- NCOR2 | c.4489dup p.R1497Pfs*36 | Frame Shift Ins (INS) | VAF 51/130 reads (39%) | called by mutect2, pindel, varscan2
- NDUFS7 | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 155/256 reads (61%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NEGR1 | c.635C>A p.P212Q | Missense Mutation (SNP) | VAF 71/251 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NKPD1 | c.1501T>A p.C501S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NKX2-4 | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- NOP53 | c.1035G>T p.E345D | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- NOTCH4 | c.4357C>A p.P1453T | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- NR3C1 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
- NSMF | c.923-3C>G | Splice Region (SNP) | VAF 105/205 reads (51%) | called by muse, mutect2, varscan2
- OBSCN | c.16513G>T p.A5505S | Missense Mutation (SNP) | VAF 208/321 reads (65%) | SIFT tolerated (0.15); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- OPHN1 | c.762A>T p.K254N | Missense Mutation (SNP) | VAF 337/613 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- OR2D3 | c.116C>A p.T39N | Missense Mutation (SNP) | VAF 129/260 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- OR5A1 | c.758T>A p.L253Q | Missense Mutation (SNP) | VAF 115/166 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OTOG | c.2021C>T p.P674L | Missense Mutation (SNP) | VAF 82/166 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- P4HA1 | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, varscan2
- PDCL2 | c.419C>A p.P140Q | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PDE8B | c.524A>G p.K175R | Missense Mutation (SNP) | VAF 138/279 reads (49%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PEX5L | c.1811C>A p.P604Q | Missense Mutation (SNP) | VAF 105/1730 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- PKHD1L1 | c.10948G>C p.D3650H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2
- PLAA | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- PLEKHH1 | c.2392A>T p.S798C | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- PLPPR4 | c.1147G>T p.A383S | Missense Mutation (SNP) | VAF 60/254 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- PMEPA1 | c.463G>T p.G155W | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POM121L2 | c.290G>T p.W97L | Missense Mutation (SNP) | VAF 53/252 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- POP1 | c.1925G>C p.G642A | Missense Mutation (SNP) | VAF 118/465 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- POTEE | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- POTEF | c.1192C>A p.P398T | Missense Mutation (SNP) | VAF 145/485 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PPIL1 | c.363G>T p.W121C | Missense Mutation (SNP) | VAF 73/256 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PPP1R42 | c.65C>G p.T22S | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRDM9 | c.1520G>T p.G507V | Missense Mutation (SNP) | VAF 119/433 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKG2 | c.2033G>T p.R678L | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- PTPRF | c.4501A>T p.S1501C | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- RAB11FIP2 | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- RBM15 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 59/223 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RGS11 | c.1123del p.E375Sfs*26 (on ENST00000397770 / NM_183337.3; = p.E354Sfs*26 on NM_003834.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/126 reads (16%) | called by mutect2, pindel, varscan2
- RNPS1 | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- RP1 | c.1649T>C p.F550S | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RPL10L | c.481G>T p.G161* | Nonsense Mutation (SNP) | VAF 58/228 reads (25%) | called by muse, mutect2, varscan2
- SEMA4B | c.2314C>T p.L772F | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETX | c.3617C>T p.S1206L | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SHANK1 | c.1109G>T p.G370V | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A14 | c.1814A>T p.N605I | Missense Mutation (SNP) | VAF 87/156 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- SLC6A4 | c.1432C>G p.L478V | Missense Mutation (SNP) | VAF 59/93 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLC9A2 | c.2230C>G p.P744A | Missense Mutation (SNP) | VAF 49/225 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- SMU1 | c.1310C>G p.S437C | Missense Mutation (SNP) | VAF 84/230 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.113); called by muse, varscan2
- SORCS3 | c.849C>A p.D283E | Missense Mutation (SNP) | VAF 103/189 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPANXB1 | c.252C>A p.N84K | Missense Mutation (SNP) | VAF 142/1536 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- SPHKAP | c.1103C>G p.P368R | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- STK36 | c.2570T>A p.L857* | Nonsense Mutation (SNP) | VAF 21/366 reads (6%) | called by muse, mutect2
- STON2 | c.1288A>T p.S430C (on ENST00000649389 / NM_001366849.2; = p.S373C on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/310 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- STYXL2 | c.1369C>A p.L457M | Missense Mutation (SNP) | VAF 71/103 reads (69%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TACC1 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 96/209 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TBL2 | c.795G>T p.E265D | Missense Mutation (SNP) | VAF 55/409 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBX18 | c.940-1G>T p.X314_splice | Splice Site (SNP) | VAF 52/265 reads (20%) | called by muse, mutect2, varscan2
- TDRD6 | c.3561G>A p.M1187I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TDRD6 | c.4783G>C p.D1595H | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TEX11 | c.2565+1G>T p.X855_splice (on ENST00000344304; = p.X840_splice on NM_031276.3) | Splice Site (SNP) | VAF 145/261 reads (56%) | called by muse, mutect2, varscan2
- THSD7A | c.2928_2929insA p.G977Rfs*41 | Frame Shift Ins (INS) | VAF 154/629 reads (24%) | called by mutect2, pindel, varscan2
- TIMD4 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 181/407 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TMEM131 | c.347A>T p.D116V | Missense Mutation (SNP) | VAF 69/351 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRAPPC3L | c.522G>T p.E174D | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAV2 | c.224C>A p.S75* | Nonsense Mutation (SNP) | VAF 89/453 reads (20%) | called by muse, mutect2, varscan2
- TRIM24 | c.2557dup p.H853Pfs*23 (on ENST00000343526 / NM_015905.3; = p.H819Pfs*23 on NM_003852.4) | Frame Shift Ins (INS) | VAF 18/72 reads (25%) | called by mutect2, pindel
- TRIM64B | c.764A>T p.D255V | Missense Mutation (SNP) | VAF 106/544 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- TRIML2 | c.128A>T p.Q43L | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT tolerated (0.85); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TUBB8B | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 248/490 reads (51%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- TXLNA | c.356G>C p.R119T | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- USH2A | c.12866A>T p.E4289V | Missense Mutation (SNP) | VAF 201/320 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- USH2A | c.410C>A p.S137Y | Missense Mutation (SNP) | VAF 241/372 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- ZC3H12B | c.1727C>A p.A576D | Missense Mutation (SNP) | VAF 389/567 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZNF18 | c.381G>T p.W127C | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- ZNF492 | c.635T>A p.L212H | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ZNF654 | c.3238C>G p.Q1080E | Missense Mutation (SNP) | VAF 83/302 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- A2M | c.1128C>T p.G376= | Silent (SNP) | VAF 206/360 reads (57%) | catalogued as rs975478908; called by muse, mutect2, varscan2
- AKNA | c.2373G>A p.G791= | Silent (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- AMER3 | c.1020C>A p.S340= | Silent (SNP) | VAF 46/128 reads (36%) | catalogued as COSV58469588; called by muse, mutect2, varscan2
- ANKRD34C | c.696C>A p.P232= | Silent (SNP) | VAF 45/150 reads (30%) | called by muse, mutect2, varscan2
- AOAH | c.606G>A p.R202= | Silent (SNP) | VAF 155/624 reads (25%) | called by muse, mutect2, varscan2
- ASAP1 | c.1767A>T p.L589= | Silent (SNP) | VAF 30/86 reads (35%) | called by mutect2, varscan2
- ASB16 | c.738G>A p.A246= | Silent (SNP) | VAF 40/67 reads (60%) | called by muse, mutect2, varscan2
- C10orf71 | c.2979G>A p.G993= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs1487688917; called by muse, mutect2, varscan2
- C19orf84 | c.519G>T p.L173= | Silent (SNP) | VAF 58/240 reads (24%) | called by muse, mutect2, varscan2
- CCDC168 | c.939C>T p.V313= | Silent (SNP) | VAF 43/110 reads (39%) | called by muse, mutect2, varscan2
- CDH23 | c.7560G>A p.E2520= | Silent (SNP) | VAF 82/156 reads (53%) | called by muse, varscan2
- CERCAM | c.558C>A p.P186= | Silent (SNP) | VAF 41/61 reads (67%) | called by muse, mutect2, varscan2
- COL11A1 | c.3357C>G p.A1119= | Silent (SNP) | VAF 21/350 reads (6%) | called by muse, mutect2
- COL19A1 | c.2145T>G p.G715= | Silent (SNP) | VAF 59/260 reads (23%) | called by muse, mutect2, varscan2
- DCAF15 | c.1161C>T p.V387= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV99586394; called by muse, mutect2, varscan2
- DCC | c.1065T>C p.S355= | Silent (SNP) | VAF 112/279 reads (40%) | called by muse, mutect2, varscan2
- DNHD1 | c.6813C>T p.D2271= | Silent (SNP) | VAF 81/474 reads (17%) | catalogued as rs754762869; ClinVar: likely benign; called by muse, mutect2, varscan2
- DUSP2 | c.351G>A p.E117= | Silent (SNP) | VAF 30/177 reads (17%) | called by muse, mutect2, varscan2
- EFCAB12 | c.270G>A p.L90= | Silent (SNP) | VAF 76/164 reads (46%) | called by muse, mutect2, varscan2
- FCGBP | c.6711C>T p.A2237= | Silent (SNP) | VAF 156/770 reads (20%) | called by muse, mutect2, varscan2
- FLNB | c.3150C>G p.L1050= | Silent (SNP) | VAF 34/189 reads (18%) | called by muse, mutect2, varscan2
- GABRG1 | c.1095T>A p.T365= | Silent (SNP) | VAF 15/140 reads (11%) | called by muse, mutect2, varscan2
- GRIN2B | c.783G>T p.L261= | Silent (SNP) | VAF 363/585 reads (62%) | catalogued as COSV74207495; called by muse, mutect2, varscan2
- HS6ST2 | c.264G>T p.A88= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as rs777877510; called by muse, mutect2, varscan2
- KCNH7 | c.2850A>C p.S950= | Silent (SNP) | VAF 143/547 reads (26%) | called by muse, mutect2, varscan2
- KCTD9 | c.759A>T p.A253= | Silent (SNP) | VAF 52/170 reads (31%) | called by muse, mutect2, varscan2
- KDM5C | c.2682G>A p.L894= | Silent (SNP) | VAF 27/89 reads (30%) | called by muse, mutect2, varscan2
- KIF6 | c.606T>A p.L202= | Silent (SNP) | VAF 34/104 reads (33%) | called by muse, mutect2, varscan2
- KIFC3 | c.744G>A p.R248= | Silent (SNP) | VAF 53/100 reads (53%) | called by muse, mutect2, varscan2
- KLRG1 | c.579T>G p.A193= | Silent (SNP) | VAF 28/268 reads (10%) | called by muse, mutect2, varscan2
- LRBA | c.6525A>G p.K2175= | Silent (SNP) | VAF 26/103 reads (25%) | called by muse, mutect2, varscan2
- LRRK2 | c.2397C>A p.A799= | Silent (SNP) | VAF 125/250 reads (50%) | catalogued as COSV100109909; called by muse, mutect2, varscan2
- LRRTM4 | c.1302C>A p.L434= | Silent (SNP) | VAF 40/114 reads (35%) | called by muse, mutect2, varscan2
- LTF | c.1761G>A p.L587= | Silent (SNP) | VAF 50/96 reads (52%) | called by muse, mutect2, varscan2
- MAP3K19 | c.2001G>T p.G667= | Silent (SNP) | VAF 84/257 reads (33%) | called by muse, mutect2, varscan2
- MED23 | c.3834G>T p.L1278= | Silent (SNP) | VAF 84/367 reads (23%) | called by muse, mutect2, varscan2
- MMS22L | c.2700G>A p.G900= | Silent (SNP) | VAF 66/329 reads (20%) | called by muse, mutect2, varscan2
- MROH2B | c.1875C>T p.C625= | Silent (SNP) | VAF 15/122 reads (12%) | catalogued as rs1190780046; called by muse, mutect2, varscan2
- MYO3B | c.1893G>T p.V631= | Silent (SNP) | VAF 157/320 reads (49%) | called by muse, mutect2, varscan2
- NKX6-1 | c.1017C>A p.I339= | Silent (SNP) | VAF 101/278 reads (36%) | called by muse, mutect2, varscan2
- NOD2 | c.2745G>T p.G915= | Silent (SNP) | VAF 155/330 reads (47%) | catalogued as COSV56050982; called by muse, mutect2, varscan2
- OBSCN | c.7320G>T p.R2440= | Silent (SNP) | VAF 54/83 reads (65%) | called by muse, mutect2
- OR56B4 | c.564G>A p.L188= | Silent (SNP) | VAF 71/150 reads (47%) | called by muse, mutect2, varscan2
- OTUD7A | c.432G>T p.L144= | Silent (SNP) | VAF 75/212 reads (35%) | called by muse, mutect2, varscan2
- PCDHB16 | c.339T>G p.P113= | Silent (SNP) | VAF 102/201 reads (51%) | called by muse, mutect2, varscan2
- PEX19 | c.762T>C p.L254= | Silent (SNP) | VAF 711/1193 reads (60%) | called by muse, mutect2, varscan2
- PGAM2 | c.519C>G p.P173= | Silent (SNP) | VAF 79/276 reads (29%) | called by muse, mutect2, varscan2
- POC1A | c.600G>A p.T200= | Silent (SNP) | VAF 49/227 reads (22%) | catalogued as rs544009996; called by muse, mutect2, varscan2
- PRDM9 | c.1521G>T p.G507= | Silent (SNP) | VAF 119/438 reads (27%) | catalogued as COSV99690060, COSV99691524; called by muse, mutect2, varscan2
- RASGRP4 | c.453C>T p.A151= | Silent (SNP) | VAF 39/225 reads (17%) | called by muse, mutect2, varscan2
- SH3TC1 | c.3687C>T p.D1229= | Silent (SNP) | VAF 13/138 reads (9%) | catalogued as rs374279230; called by muse, mutect2
- SLC12A5 | c.864C>A p.L288= (on ENST00000454036 / NM_001134771.2; = p.L265= on NM_020708.5) | Silent (SNP) | VAF 61/233 reads (26%) | catalogued as COSV99715408; called by muse, mutect2, varscan2
- SLITRK3 | c.681C>A p.L227= | Silent (SNP) | VAF 36/358 reads (10%) | called by muse, mutect2, varscan2
- SMU1 | c.1530C>G p.L510= | Silent (SNP) | VAF 66/248 reads (27%) | called by muse, varscan2
- SOBP | c.105A>T p.A35= | Silent (SNP) | VAF 78/356 reads (22%) | called by muse, mutect2, varscan2
- SORCS2 | c.2793G>C p.T931= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as COSV61163347; called by muse, mutect2, varscan2
- STXBP6 | c.336A>T p.V112= | Silent (SNP) | VAF 49/291 reads (17%) | called by muse, mutect2, varscan2
- TBC1D5 | c.1611T>C p.S537= | Silent (SNP) | VAF 140/303 reads (46%) | called by muse, varscan2
- TMPRSS11B | c.285C>A p.V95= | Silent (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
- TTN | c.18891T>C p.L6297= (on ENST00000591111; = p.L5370= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/289 reads (21%) | catalogued as COSV60417940; called by muse, mutect2, varscan2
- TTN | c.7995C>A p.I2665= (on ENST00000591111; = p.I2619= on NM_003319.4) | Silent (SNP) | VAF 200/852 reads (23%) | called by muse, mutect2, varscan2
- UROC1 | c.1716T>A p.A572= | Silent (SNP) | VAF 160/441 reads (36%) | called by muse, mutect2, varscan2
- USP5 | c.102C>T p.F34= | Silent (SNP) | VAF 139/224 reads (62%) | called by muse, mutect2, varscan2
- UTP20 | c.1974C>A p.V658= | Silent (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- ZDHHC21 | c.699C>T p.F233= | Silent (SNP) | VAF 44/85 reads (52%) | catalogued as rs368457463; called by muse, mutect2, varscan2
- ZNF398 | c.912A>G p.T304= (on ENST00000475153 / NM_170686.3; = p.T133= on NM_020781.4) | Silent (SNP) | VAF 51/223 reads (23%) | called by muse, mutect2, varscan2
- AC004890.2 | n.2359del | RNA (DEL) | VAF 10/42 reads (24%) | called by mutect2, pindel, varscan2
- AC087482.1 | n.693C>G | RNA (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2, varscan2
- C10orf88B | n.777C>T | RNA (SNP) | VAF 19/60 reads (32%) | catalogued as rs757262036; called by muse, mutect2
- C20orf197 | n.672C>T | RNA (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
- CBX2 | c.182+36G>C | Intron (SNP) | VAF 18/98 reads (18%) | called by muse, mutect2
- CDKL4 | chr2:39176065 T>C | 3'Flank (SNP) | VAF 34/304 reads (11%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56811957 G>A | 3'Flank (SNP) | VAF 56/452 reads (12%) | catalogued as rs539878010; called by muse, varscan2
- CICP28 | chr7:56812012 G>A | 3'Flank (SNP) | VAF 44/281 reads (16%) | catalogued as rs1317255750; called by muse, varscan2
- DCHS2 | n.281T>C | RNA (SNP) | VAF 10/254 reads (4%) | called by muse, mutect2
- DDX39B | c.1271-22C>T | Intron (SNP) | VAF 28/125 reads (22%) | called by muse, mutect2, varscan2
- DOCK4 | c.5014-700C>A | Intron (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- ECM1 | c.304+12C>T | Intron (SNP) | VAF 142/209 reads (68%) | catalogued as rs764394055, COSV60875806; called by muse, mutect2, varscan2
- FAM161A | c.*682C>T | 3'UTR (SNP) | VAF 18/33 reads (55%) | called by muse, mutect2, varscan2
- FRYL | c.-81+3567T>C | Intron (SNP) | VAF 17/35 reads (49%) | called by muse, varscan2
- GDAP1 | c.*1807C>T | 3'UTR (SNP) | VAF 14/48 reads (29%) | catalogued as rs1476040015; called by muse, mutect2, varscan2
- IL7R | c.801-89T>C | Intron (SNP) | VAF 102/322 reads (32%) | called by muse, mutect2, varscan2
- KDM4C | c.2425-27199G>A | Intron (SNP) | VAF 14/103 reads (14%) | catalogued as rs1274615007; called by muse, mutect2, varscan2
- KMT5C | c.570+1027G>T | Intron (SNP) | VAF 52/206 reads (25%) | called by muse, mutect2, varscan2
- LRRC69 | c.933+5974A>T | Intron (SNP) | VAF 18/207 reads (9%) | called by muse, mutect2
- MAP2K3 | c.49+6505G>T | Intron (SNP) | VAF 50/152 reads (33%) | catalogued as rs1310152388; called by muse, mutect2, varscan2
- METTL22 | c.*150G>C | 3'UTR (SNP) | VAF 33/81 reads (41%) | called by muse, mutect2, varscan2
- METTL8 | c.861-174A>G | Intron (SNP) | VAF 165/369 reads (45%) | catalogued as rs1175272036; called by muse, mutect2, varscan2
- MIR890 | n.56T>A | RNA (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- PDIA3P1 | n.1350G>A | RNA (SNP) | VAF 106/532 reads (20%) | called by muse, mutect2, varscan2
- R3HDM1 | c.-36C>T | 5'UTR (SNP) | VAF 31/150 reads (21%) | called by muse, mutect2, varscan2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 10/153 reads (7%) | catalogued as rs910081914; called by muse, mutect2
- RNA5-8SP2 | chr16:34159745 G>T | 5'Flank (SNP) | VAF 21/124 reads (17%) | catalogued as rs796298062; called by muse, mutect2, varscan2
- RNGTT | chr6:88966031 T>G | 5'Flank (SNP) | VAF 76/305 reads (25%) | called by muse, mutect2, varscan2
- SERINC5 | c.1238+2303G>C | Intron (SNP) | VAF 56/115 reads (49%) | called by muse, mutect2, varscan2
- SLC7A6 | c.524-376C>G | Intron (SNP) | VAF 33/149 reads (22%) | called by muse, mutect2, varscan2
- SNORD116-11 | n.9G>T | RNA (SNP) | VAF 55/267 reads (21%) | called by muse, mutect2, varscan2
- TMEM161B | c.290-1041G>T | Intron (SNP) | VAF 13/94 reads (14%) | called by muse, mutect2, varscan2
- TPH2 | c.-8C>T | 5'UTR (SNP) | VAF 196/420 reads (47%) | called by muse, mutect2, varscan2
- ZNF131 | chr5:43120031 C>G | 5'Flank (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
